Somatic mutation profile of tumor specimen 0DTUXC from CCDI case PBCJFG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,007 days).
Specimen 0DTUXC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f02c61af-91ed-4c6a-83a6-43fecb78aeec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTUX4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6fa1fe3-7df6-483d-a14a-9f81e9e6160e

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 2, Silent 2, Intron 2, Frame Shift Ins 1, 5'UTR 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC2H1 | c.11106G>T p.E3702D | Missense Mutation (SNP) | VAF 284/655 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs113707199; called by muse, mutect2, varscan2
- EAF2 | c.334dup p.T112Nfs*4 | Frame Shift Ins (INS) | VAF 341/726 reads (47%) | catalogued as rs746509911; called by mutect2, varscan2
- LTB4R | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 285/612 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs150532344, COSV99350473; called by muse, mutect2, varscan2
- TGM6 | c.1835T>C p.V612A | Missense Mutation (SNP) | VAF 507/1107 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as rs1390765161; called by muse, mutect2, varscan2
- AP5M1 | c.75-1G>C p.X25_splice | Splice Site (SNP) | VAF 63/457 reads (14%) | called by muse, mutect2, varscan2
- DNAH3 | c.10325A>G p.N3442S | Missense Mutation (SNP) | VAF 449/934 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- OR6B3 | c.715T>A p.F239I | Missense Mutation (SNP) | VAF 900/1948 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2
- PPP6R3 | c.1909C>T p.R637* (on ENST00000393800 / NM_001352375.2; = p.R557* on NM_018312.5) | Nonsense Mutation (SNP) | VAF 493/1149 reads (43%) | called by muse, mutect2, varscan2
- THSD7B | c.851dup p.Y284* | Nonsense Mutation (INS) | VAF 150/1288 reads (12%) | called by mutect2, varscan2
- TOP1MT | c.1428C>T p.F476= | Silent (SNP) | VAF 1298/2030 reads (64%) | catalogued as rs372788685; called by muse, mutect2, varscan2
- TRPM3 | c.1413C>A p.I471= (on ENST00000357533 / NM_001366142.2; = p.I316= on NM_020952.6) | Silent (SNP) | VAF 452/1058 reads (43%) | catalogued as COSV62594553; called by muse, mutect2, varscan2
- EBPL | c.-18G>A | 5'UTR (SNP) | VAF 203/507 reads (40%) | called by muse, mutect2, varscan2
- EDA2R | c.*82G>C | 3'UTR (SNP) | VAF 414/437 reads (95%) | called by muse, mutect2, varscan2
- KRT15 | c.1273+65C>T | Intron (SNP) | VAF 298/915 reads (33%) | catalogued as rs754588058, COSV99562916; called by muse, mutect2, varscan2
- NAALADL1 | c.2036+56C>G | Intron (SNP) | VAF 153/327 reads (47%) | called by muse, mutect2, varscan2
